APOLLO case AP-64ZX — APOLLO2: Proteogenomic characterization of ovarian serous cystadenocarcinoma (APOLLO-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/bddbf9f5-a46e-472e-98b0-0c46d8e6f743

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. High-grade serous carcinoma: Tissue or organ of origin: Ovary; Site of resection or biopsy: Abdomen, NOS; Classification of tumor: metastasis; Age at diagnosis: 65.9 years (24,069 days); Residual disease: R0.

Biospecimens (2 samples)
- Sample AP-64ZX_normal: Tissue type: Normal; Specimen type: Peripheral Blood NOS; Biospecimen anatomic site: Diaphragm; Preservation method: Frozen.
- Sample AP-64ZX_tumor: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Diaphragm; Preservation method: OCT; Diagnosis pathologically confirmed: Yes.
